TCGA case TCGA-G4-6297 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/622cc1c4-d721-4b5c-a88b-216d6368660b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Alive.

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,103 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,506 days (6.9 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 36; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 103 days; Prescribed dose: 5; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 103 days; Prescribed dose: 400; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 103 days; Prescribed dose: 85; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Initial disease status: Progressive Disease; Days to treatment start: 565 days (1.5 years); Days to treatment end: 726 days (2.0 years); Number of cycles: 23; Treatment dose: 11,210 mg; Prescribed dose: 760; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 565 days (1.5 years); Days to treatment end: 719 days (2.0 years); Number of cycles: 12; Treatment dose: 4,104 mg; Prescribed dose: 342; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,041 days (2.9 years); Days to treatment end: 1,181 days (3.2 years); Number of cycles: 10; Treatment dose: 4,310 mg; Prescribed dose: 445; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 1,041 days (2.9 years); Days to treatment end: 1,181 days (3.2 years); Number of cycles: 10; Treatment dose: 7,900 mg; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin; Initial disease status: Recurrent Disease; Days to treatment start: 1,041 days (2.9 years); Days to treatment end: 1,181 days (3.2 years); Number of cycles: 10; Treatment dose: 7,900 mg; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,041 days (2.9 years); Days to treatment end: 1,076 days (2.9 years); Number of cycles: 3; Treatment dose: 510 mg; Prescribed dose: 170; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,377 days (3.8 years); Number of cycles: 61; Treatment dose: 30,661 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 712; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Progressive Disease; Days to treatment start: 1,377 days (3.8 years); Days to treatment end: 1,636 days (4.5 years); Number of cycles: 13; Treatment dose: 655,200 mg; Prescribed dose: 3600; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,687 days (4.6 years); Days to treatment end: 2,373 days (6.5 years); Number of cycles: 45; Treatment dose: 13,386 mg; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 2,450 days (6.7 years); Days to treatment end: 2,450 days (6.7 years); Number of cycles: 1; Treatment dose: 792 mg; Prescribed dose: 792; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Initial disease status: Progressive Disease; Days to treatment start: 2,450 days (6.7 years); Number of cycles: 4; Treatment dose: 630 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 168; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 56.2 years (20,542 days); Days to diagnosis: 439 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 57.8 years (21,116 days); Days to diagnosis: 1,013 days (2.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
4. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 61.6 years (22,497 days); Days to diagnosis: 2,394 days (6.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,394 days (6.6 years); Treatment anatomic sites: Other.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 439 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 439 days (1.2 years).
- Day 1,013 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,013 days (2.8 years).
- Days to follow up: 2,289 days (6.3 years); Disease response: With Tumor.
- Day 2,394 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 2,394 days (6.6 years).
- Days to follow up: 2,506 days (6.9 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G4-6297-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.2.
  Slide TCGA-G4-6297-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 5; Percent stromal cells: 20.
  Slide TCGA-G4-6297-01A-01-BS1: Section location: Bottom; Percent tumor cells: 62; Percent tumor nuclei: 80; Percent normal cells: 8; Percent necrosis: 5; Percent stromal cells: 25.
- Sample TCGA-G4-6297-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G4-6297-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-G4-6297-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Weight kg at diagnosis: 64 kg; Lymph nodes examined: Yes; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 3; Therapy regimen: Recurrence.
- Drug treatment 3: Regimen number: 4; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 6; Therapy regimen: Progression.
- Drug treatment 7: Regimen number: 5; Therapy regimen: Progression.
- Drug treatment 8: Regimen number: 2; Therapy regimen: Progression.
- Drug treatment 9: Regimen number: 4; Pharmaceutical therapy drug name: Xeloda; Therapy regimen: Progression.
- Drug treatment 9, Route of administrations: Route of administration: PO.
- Drug treatment 11: Regimen number: 3; Therapy regimen: Progression.
- Drug treatment 15: Regimen number: 1; Pharmaceutical therapy drug name: Avastin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,506 days; disease-specific survival: no event (censored), 2,506 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 439 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G4-6297-01A-11D-1717-01): tumor purity 0.48, ploidy 2.91, whole-genome doublings 1.
